OHSU case 3820 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f844660f-38f2-4b36-a5df-d9a372c6945e

Demographics
Sex at birth: male.

Diagnoses (1)
1. Chronic neutrophilic leukemia: ICD-O-3 morphology code: 9963/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.0 years (27,393 days); Days to last follow up: 928 days (2.5 years).

Biospecimens (1 sample)
- Sample 2148D: Tissue type: Tumor; Preservation method: Snap Frozen.
